Gene-level copy-number profile of tumor specimen TCGA-97-8174-01A from TCGA case TCGA-97-8174, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 67.7 years (24,725 days).
Specimen TCGA-97-8174-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.73e39095-4b17-43c9-9b92-6dfcf3401754.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-97-8174-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f19c782d-21a1-4002-9bfa-b21efb48be52

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 20,941; copy number 2: 30,912; copy number 3: 7,765; copy number 4: 194; copy number 5: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-97-8174-01A-11D-2283-01): tumor purity 0.3, ploidy 3.62, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:123,519,697–123,685,323, 2 genes, copy number 5 (within-gene range 4–5): AL445259.1, AL133257.1.

Autosomal genes at a single copy (total copy number 1): 18,560. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
